Somatic mutation profile of tumor specimen TCGA-K1-A6RU-01A (aliquot TCGA-K1-A6RU-01A-11D-A32I-09) from TCGA case TCGA-K1-A6RU, project TCGA-SARC (Sarcoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Fibromyxosarcoma; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of lower limb and hip; Age at diagnosis: 66.7 years (24,356 days).
Specimen TCGA-K1-A6RU-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b3b60cc4-d472-4dc3-8a2a-a3d46a308441.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-K1-A6RU-10A (Blood Derived Normal), aliquot TCGA-K1-A6RU-10A-01D-A32I-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b097ad52-9dbb-4fba-a131-a6c8de9f51ea

The open-access MAF lists 35 somatic variants for this specimen: 20 protein-altering or splice-affecting, 13 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 14, Silent 13, Nonsense Mutation 4, Intron 2, Splice Site 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADGRL2 | c.359A>G p.Y120C | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99587461; called by muse, mutect2, varscan2
- ANAPC1 | c.1317A>T p.Q439H | Missense Mutation (SNP) | VAF 27/98 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.276); catalogued as COSV100594560; called by muse, mutect2, varscan2
- C8A | c.1381-2A>G p.X461_splice | Splice Site (SNP) | VAF 12/62 reads (19%) | catalogued as COSV100776454; called by muse, mutect2, varscan2
- CDK12 | c.1916A>T p.D639V | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.093); catalogued as COSV101420382; called by muse, mutect2, varscan2
- CFAP53 | c.1112A>C p.K371T | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated (0.59); PolyPhen benign (0.257); catalogued as COSV101274958; called by muse, mutect2
- CFH | c.2815C>T p.H939Y | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.454); catalogued as COSV66414714, COSV66415264; called by mutect2, varscan2
- CXADR | c.941C>G p.S314C | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.907); catalogued as rs777505577, COSV99515060, COSV99515136; called by muse, varscan2
- FRG2 | c.514C>T p.R172* | Nonsense Mutation (SNP) | VAF 15/89 reads (17%) | catalogued as COSV66459881; called by muse, mutect2, varscan2
- HOOK1 | c.1879G>C p.A627P | Missense Mutation (SNP) | VAF 23/78 reads (29%) | SIFT tolerated (0.18); PolyPhen benign (0.029); catalogued as COSV100969002; called by muse, mutect2, varscan2
- LYNX1-SLURP2 | c.318C>A p.C106* | Nonsense Mutation (SNP) | VAF 27/95 reads (28%) | catalogued as COSV100235462; called by muse, mutect2, varscan2
- MS4A14 | c.260C>A p.A87E | Missense Mutation (SNP) | VAF 17/21 reads (81%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV55729897; called by muse, mutect2, varscan2
- PIKFYVE | c.391C>T p.L131F | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.991); catalogued as rs1462442548, COSV100010022; called by muse, mutect2, varscan2
- PRDM2 | c.4780G>T p.A1594S | Missense Mutation (SNP) | VAF 3/40 reads (8%) | SIFT tolerated (0.22); PolyPhen benign (0.236); catalogued as COSV99341051; called by muse, mutect2
- RALGPS2 | c.923C>G p.S308C | Missense Mutation (SNP) | VAF 7/79 reads (9%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.848); catalogued as COSV100243614; called by muse, mutect2, varscan2
- RB1 | c.1166T>G p.L389* | Nonsense Mutation (SNP) | VAF 7/13 reads (54%) | catalogued as CM071074, COSV57298834, COSV99923545; called by muse, mutect2, varscan2
- RGMA | c.1312G>A p.A438T | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs759625610, COSV61236492; called by muse, mutect2, varscan2
- SHC4 | c.1651A>T p.S551C | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100194271; called by muse, mutect2, varscan2
- UNC13C | c.6133C>T p.Q2045* | Nonsense Mutation (SNP) | VAF 6/22 reads (27%) | catalogued as COSV99512807; called by muse, mutect2
- XPO1 | c.536T>C p.F179S | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101294169; called by muse, mutect2, varscan2
- ATRX | c.6423_6426del p.S2142Mfs*24 | Frame Shift Del (DEL) | VAF 53/143 reads (37%) | called by mutect2, pindel, varscan2
- CACNA1H | c.3003C>T p.F1001= | Silent (SNP) | VAF 5/12 reads (42%) | catalogued as rs761698159, COSV100671109; called by muse, mutect2, varscan2
- IRS1 | c.1209C>T p.T403= | Silent (SNP) | VAF 4/38 reads (11%) | catalogued as rs529655323, COSV100524135, COSV59333187; called by muse, mutect2
- KRT6B | c.1479C>A p.V493= | Silent (SNP) | VAF 3/38 reads (8%) | catalogued as COSV99360518; called by muse, mutect2
- MROH2B | c.2847G>A p.A949= | Silent (SNP) | VAF 13/61 reads (21%) | catalogued as rs371233888; called by muse, mutect2, varscan2
- NPHS1 | c.3243C>T p.V1081= | Silent (SNP) | VAF 9/41 reads (22%) | catalogued as rs370276697; ClinVar: likely benign; called by muse, mutect2, varscan2
- REPS2 | c.1545A>G p.P515= | Silent (SNP) | VAF 27/66 reads (41%) | catalogued as COSV100380892; called by muse, mutect2, varscan2
- SLC25A3 | c.99C>T p.S33= | Silent (SNP) | VAF 8/50 reads (16%) | catalogued as COSV99499010; called by muse, mutect2, varscan2
- SORL1 | c.2808G>A p.T936= | Silent (SNP) | VAF 4/29 reads (14%) | catalogued as rs370296806; called by mutect2, varscan2
- TBCE | c.258G>A p.K86= | Silent (SNP) | VAF 6/60 reads (10%) | catalogued as COSV100782985; called by muse, mutect2, varscan2
- THSD7B | c.759G>T p.L253= | Silent (SNP) | VAF 11/39 reads (28%) | catalogued as COSV55745624, COSV99745779; called by muse, mutect2, varscan2
- TMPRSS15 | c.2806C>T p.L936= | Silent (SNP) | VAF 9/27 reads (33%) | catalogued as COSV99517129; called by muse, mutect2, varscan2
- UGT8 | c.858T>C p.H286= | Silent (SNP) | VAF 13/41 reads (32%) | catalogued as COSV100179019; called by muse, mutect2, varscan2
- YRDC | c.813G>T p.L271= | Silent (SNP) | VAF 18/59 reads (31%) | catalogued as COSV100203840; called by muse, mutect2, varscan2
- SLC25A3 | c.282+228C>A | Intron (SNP) | VAF 6/47 reads (13%) | catalogued as rs1063501, COSV99499014; called by mutect2, varscan2
- ZNF160 | c.271+723A>C | Intron (SNP) | VAF 10/72 reads (14%) | catalogued as COSV100762256, COSV100762287; called by muse, mutect2, varscan2
